Somatic mutation profile of tumor specimen 0DHV6E from CCDI case PBBPNV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.8 years (3,576 days).
Specimen 0DHV6E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b161e544-b747-476f-ae3b-3564a76eeeff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHV67 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31e101c1-48b2-46d1-8006-d2abe354e15f

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, 3'Flank 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FCGBP | c.1975G>A p.A659T | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs779220407; called by muse, mutect2, varscan2
- PLCL1 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 357/843 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141588918; called by muse, mutect2, varscan2
- VIPR2 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 110/504 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs376902530; called by muse, mutect2, varscan2
- MMP13 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 301/812 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PFKFB2 | chr1:207078998 G>A | 3'Flank (SNP) | VAF 112/632 reads (18%) | catalogued as rs144692490; called by muse, mutect2, varscan2
- TMEM52 | c.170+79del | Intron (DEL) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- ZC3H14 | chr14:88563036 del A | 5'Flank (DEL) | VAF 2/12 reads (17%) | called by mutect2, varscan2
- ZC3H14 | c.-97G>T | 5'UTR (SNP) | VAF 2/14 reads (14%) | called by mutect2, varscan2
